Somatic mutation profile of tumor specimen MP2PRT-PANWSP-TMP1-A (aliquot MP2PRT-PANWSP-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANWSP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,197 days).
Specimen MP2PRT-PANWSP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68026b8e-edbf-429a-84ff-94cb69f0215f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWSP-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWSP-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/032abfcd-7aa9-4424-bb4a-646ff2c8dd60

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.1586A>T p.D529V | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as CM074733; called by muse, mutect2, varscan2
- H4C5 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 143/213 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as rs752651799; called by muse, mutect2, varscan2
- ZNF488 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 185/432 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
